Somatic mutation profile of tumor specimen TCGA-L3-A4E7-01A (aliquot TCGA-L3-A4E7-01A-11D-A257-08) from TCGA case TCGA-L3-A4E7, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.8 years (26,232 days).
Specimen TCGA-L3-A4E7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 272c9bf0-3d2c-4db6-a6f6-89f9c4c6ad2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L3-A4E7-10A (Blood Derived Normal), aliquot TCGA-L3-A4E7-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/348bf03b-84f0-4ab2-8042-51c28b2be6ba

The open-access MAF lists 107 somatic variants for this specimen: 84 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 76, Silent 23, Nonsense Mutation 3, Frame Shift Del 3, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 78/198 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC090517.4 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV99974191; called by muse, mutect2
- ACTR10 | c.894A>T p.Q298H | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as COSV99580990; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4159C>T p.L1387F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV101000429; called by muse, mutect2, varscan2
- AKAP6 | c.6035C>G p.A2012G | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99799316; called by muse, mutect2, varscan2
- APOB | c.4961C>A p.T1654N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99028791; called by muse, mutect2, varscan2
- ARHGAP36 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs1256533982, COSV52267805, COSV99357197; called by muse, mutect2, varscan2
- BAAT | c.367A>G p.K123E | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.043); catalogued as COSV99408408; called by muse, mutect2, varscan2
- BPIFA1 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1410623337, COSV100845632; called by muse, mutect2, varscan2
- BSN | c.8134C>T p.R2712C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs759920256, COSV99607663; called by muse, mutect2, varscan2
- CCDC39 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99867855; called by muse, mutect2, varscan2
- CD1A | c.93G>T p.W31C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99192245; called by muse, mutect2
- CDH9 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); catalogued as COSV99142311; called by muse, mutect2, varscan2
- CFH | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661358; called by muse, mutect2, varscan2
- CHRD | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99200268; called by muse, mutect2, varscan2
- COG2 | c.234G>A p.L78= | Splice Region (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100794632; called by muse, mutect2, varscan2
- COL11A1 | c.2329A>G p.K777E | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100615532; called by muse, mutect2, varscan2
- COL12A1 | c.4021G>T p.V1341F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100485583; called by muse, mutect2, varscan2
- CTNND2 | c.1257C>A p.H419Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100473499; called by muse, mutect2, varscan2
- DBF4 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as rs1463098793; called by muse, mutect2
- DHCR7 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100831789; called by muse, mutect2, varscan2
- DHTKD1 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1297099391, COSV53805790; called by muse, mutect2, varscan2
- DNAH7 | c.9611G>A p.R3204H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs199798030; called by muse, mutect2, varscan2
- DNAJA1 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as COSV100438425; called by muse, mutect2, varscan2
- DTX2 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100184459; called by muse, mutect2, varscan2
- DUOX2 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV101199643; called by muse, mutect2, varscan2
- EIF2AK3 | c.2038A>T p.T680S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as COSV100303557; called by muse, mutect2, varscan2
- FCAR | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100629009; called by muse, mutect2, varscan2
- FNIP2 | c.3117A>T p.L1039F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100032316; called by muse, mutect2
- FOLH1 | c.1199G>T p.R400M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99922864; called by muse, mutect2, varscan2
- FREM2 | c.2056C>A p.L686I | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99747552; called by muse, mutect2, varscan2
- GABRR3 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101512269; called by muse, mutect2, varscan2
- GMFG | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV99453281; called by muse, mutect2, varscan2
- HCN1 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.084); catalogued as COSV100299241, COSV57523540; called by muse, mutect2, varscan2
- HNRNPUL2 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584565; called by muse, mutect2, varscan2
- HSPA13 | c.1285T>C p.S429P | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579950; called by muse, mutect2, varscan2
- HUWE1 | c.3281C>T p.P1094L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs782205649, COSV99470811; called by muse, mutect2
- KANSL1L | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762505094, COSV55993885; called by muse, mutect2, varscan2
- KIAA1109 | c.11654A>G p.Y3885C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99148647; called by muse, mutect2
- KIF1A | c.3169G>C p.V1057L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV100240184; called by muse, mutect2, varscan2
- LHFPL3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs373201390; called by muse, mutect2, varscan2
- LRP1B | c.4654G>T p.A1552S | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as COSV101254187, COSV67211893; called by muse, mutect2, varscan2
- LRRC66 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100602876; called by muse, mutect2, varscan2
- LRRC66 | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs747783801, COSV100602878; called by muse, mutect2, varscan2
- LRRK2 | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV100109551, COSV100111775; called by muse, mutect2, varscan2
- MAPKBP1 | c.3530G>T p.S1177I (on ENST00000456763 / NM_001128608.2; = p.S1171I on NM_014994.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV99529071; called by muse, mutect2, varscan2
- MYH2 | c.5352C>A p.H1784Q | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV55440488; called by muse, mutect2, varscan2
- NAA25 | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99927405; called by muse, mutect2, varscan2
- NCAPD2 | c.4181C>T p.A1394V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs773097640, COSV99975424; called by muse, mutect2, varscan2
- NPSR1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV100705955, COSV62198748; called by muse, mutect2, varscan2
- NR1H4 | c.485G>T p.R162M (on ENST00000551379 / NM_001206993.2; = p.R152M on NM_005123.4) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500210; called by muse, mutect2, varscan2
- NR1H4 | c.486G>T p.R162S (on ENST00000551379 / NM_001206993.2; = p.R152S on NM_005123.4) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99500212; called by muse, mutect2, varscan2
- NRCAM | c.1333G>A p.A445T (on ENST00000379028 / NM_001371124.1; = p.A439T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1319574637, COSV100694448; called by muse, mutect2, varscan2
- OR10S1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101602454; called by muse, mutect2, varscan2
- OR4K15 | c.212T>A p.L71H (on ENST00000305051; = p.L47H on NM_001005486.1) | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100521002; called by muse, mutect2, varscan2
- OR9Q2 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100285371, COSV100285452, COSV61112079; called by muse, mutect2, varscan2
- PCDHA7 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100971311, COSV65346053; called by muse, mutect2, varscan2
- PLCL1 | c.2256A>G p.I752M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as rs1199836810, COSV101406839; called by muse, mutect2, varscan2
- PLEKHB2 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301561; called by muse, mutect2, varscan2
- PLXNA4 | c.3791C>A p.S1264Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100323155; called by muse, mutect2, varscan2
- RCSD1 | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100827595; called by muse, mutect2, varscan2
- SNX27 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs1361143289, COSV100918990; called by muse, mutect2, varscan2
- SSH1 | c.1519dup p.L507Pfs*17 | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs781664894; called by mutect2, varscan2
- SSH3 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs148649808; called by muse, mutect2, varscan2
- STAB2 | c.5216G>T p.R1739I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101185730, COSV66343562; called by muse, mutect2, varscan2
- SYNE1 | c.2761C>A p.H921N (on ENST00000367255 / NM_182961.4; = p.H928N on NM_033071.3) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99551003; called by muse, mutect2, varscan2
- SYTL2 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100313809; called by muse, mutect2, varscan2
- TAOK2 | c.3364G>T p.G1122C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99662914; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1042A>C p.M348L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99304831; called by muse, mutect2, varscan2
- TTN | c.7846A>G p.T2616A (on ENST00000591111; = p.T2570A on NM_003319.4) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | PolyPhen benign (0.124); catalogued as COSV100600578; called by muse, mutect2, varscan2
- TUBGCP6 | c.4715G>T p.G1572V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99955091; called by muse, mutect2, varscan2
- UBR5 | c.5608C>T p.H1870Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99639948; called by muse, mutect2, varscan2
- UGT2B15 | c.1412A>G p.H471R | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs534822323, COSV100592244; called by muse, mutect2, varscan2
- UGT8 | c.830A>T p.Q277L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100179054; called by muse, mutect2, varscan2
- XAB2 | c.2369G>C p.R790P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV50338594, COSV99350097; called by muse, mutect2, varscan2
- ZMAT1 | c.1653G>T p.R551S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV100858719; called by muse, mutect2, varscan2
- ZNF567 | c.1667C>G p.T556S (on ENST00000536254 / NM_001322913.1; = p.T525S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.078); catalogued as rs745326808, COSV100658672; called by muse, mutect2, varscan2
- ZNF786 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs765306158, COSV60276701, COSV60277304; called by muse, mutect2, varscan2
- ZNF98 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100757354, COSV63338689; called by muse, mutect2
- BRIP1 | c.3185_3186del p.T1062Ifs*18 | Frame Shift Del (DEL) | VAF 59/239 reads (25%) | called by pindel, varscan2
- NAT8L | c.604del p.H202Tfs*77 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- PPP1R3A | c.615del p.E206Sfs*36 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- ZC3H7B | c.1953G>A p.M651I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- ATP2B3 | c.1146C>T p.T382= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs186942321, COSV99683516; called by muse, mutect2
- C6 | c.1782C>A p.P594= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs545271270, COSV99666748; called by muse, mutect2, varscan2
- CR2 | c.1161C>G p.G387= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100889552; called by muse, mutect2, varscan2
- DNAH17 | c.7377G>T p.T2459= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV67759319; called by muse, mutect2, varscan2
- ERMARD | c.1218G>C p.L406= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100824543, COSV64647986; called by muse, mutect2
- GCN1 | c.348C>T p.A116= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV100324816; called by muse, mutect2, varscan2
- GLI1 | c.1932G>A p.Q644= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1479201313, COSV99953813; called by muse, mutect2, varscan2
- GRIK1 | c.2316C>A p.G772= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100516163; called by muse, mutect2, varscan2
- HDAC10 | c.225C>T p.T75= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99299157; called by muse, mutect2, varscan2
- HDX | c.672A>T p.P224= | Silent (SNP) | VAF 61/116 reads (53%) | catalogued as COSV52975191, COSV99946871; called by muse, mutect2, varscan2
- KDM2B | c.2376C>A p.R792= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as COSV100997297; called by muse, mutect2, varscan2
- KRTAP10-5 | c.516C>T p.C172= | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as rs1441042906, COSV100552383; called by muse, mutect2, varscan2
- MITF | c.471G>A p.L157= (on ENST00000448226 / NM_006722.3; = p.L51= on NM_000248.4) | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1374661260, COSV100096654; called by muse, mutect2, varscan2
- NOS2 | c.1566G>A p.V522= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100569539; called by muse, mutect2, varscan2
- NPSR1 | c.762G>T p.G254= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100705958, COSV62208531; called by muse, mutect2, varscan2
- OR2D2 | c.609G>A p.G203= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs768698395, COSV100203758; called by muse, mutect2, varscan2
- PDZRN3 | c.2806A>C p.R936= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99728185; called by muse, mutect2, varscan2
- POLQ | c.5535G>T p.R1845= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV99951828; called by muse, mutect2, varscan2
- SLC12A5 | c.387G>T p.P129= (on ENST00000454036 / NM_001134771.2; = p.P106= on NM_020708.5) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99715580; called by muse, mutect2, varscan2
- SLC8A1 | c.576C>T p.D192= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs755112990, COSV60478201; called by muse, mutect2, varscan2
- SPINK7 | c.57C>T p.S19= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99199119; called by muse, mutect2, varscan2
- ZNF302 | c.123C>G p.V41= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as COSV101416444; called by muse, mutect2, varscan2
- ZNF79 | c.1449G>T p.R483= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as COSV100687970; called by muse, mutect2, varscan2
